Somatic mutation profile of tumor specimen ALCH-B2PM-TTP1-A (aliquot ALCH-B2PM-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2PM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.1 years (25,239 days).
Specimen ALCH-B2PM-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a7a1ed6-08ec-4dde-ad2e-f21c122ee8bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2PM-NB1-A (Blood Derived Normal), aliquot ALCH-B2PM-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3270a49e-dcaf-4ea0-9340-e06142bbb800

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 15/173 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2
- CPS1 | c.4232C>T p.P1411L | Missense Mutation (SNP) | VAF 22/691 reads (3%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.982); catalogued as rs1202306773, CM063922; ClinVar: uncertain significance; called by muse, mutect2
- DNAH10 | c.9595G>T p.A3199S (on ENST00000409039; = p.A3138S on NM_207437.3) | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775366865, COSV69004368; called by muse, mutect2
- GLUL | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 20/662 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1179181645; called by muse, mutect2
- GRAP2 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV104417477; called by muse, mutect2
- LAMA4 | c.4573G>A p.A1525T (on ENST00000230538 / NM_001105206.3; = p.A1518T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs1161275121; called by muse, mutect2
- ARVCF | c.1776C>G p.Y592* | Nonsense Mutation (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- G6PC2 | c.629C>G p.T210S | Missense Mutation (SNP) | VAF 21/397 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.388); called by muse, mutect2
- SP9 | c.816C>T p.A272= | Silent (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- DCLRE1CP1 | n.187C>A | RNA (SNP) | VAF 18/342 reads (5%) | catalogued as rs1430005291; called by muse, mutect2
